TARGET case TARGET-15-SJMPAL042796 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c3fc4a9-1ddd-4f62-8d4e-1c4fe72cbcc9

Demographics
Sex at birth: male; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 4.0 years (1,457 days); Year of diagnosis: 2011; Days to last follow up: 1,215 days (3.3 years).

Follow-up (1 entry)
- Days to follow up: 1,215 days (3.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,215; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 105 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL042796-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1215
- Protocol: Japan (TCCSG)
- WBC at Diagnosis: 104.6
- Initial Therapy: AML
- Karyotype: 46,XY,add(5)(q13) [7] / 47,idem,+21 [3] / 46,XY,add(5)(q13) [2] /46,XY[8]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
